Gene-level copy-number profile of tumor specimen TCGA-24-2023-01A from TCGA case TCGA-24-2023, project TCGA-OV (Ovarian Serous Cystadenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Ovary; FIGO stage: Stage IIIA; Tumor grade: G3; Age at diagnosis: 54.5 years (19,901 days).
Specimen TCGA-24-2023-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-OV.ae92c485-b80f-452c-b45d-013c366a9e89.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-24-2023-11A (solid tissue normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 824 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/774d4a07-8210-43a8-a992-c6a046f40807

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 44; copy number 1: 3; copy number 2: 20,307; copy number 3: 1,571; copy number 4: 30,439; copy number 5: 163; copy number 6: 5,915; copy number 7: 157; copy number 8: 529; copy number 9: 302; copy number 10: 303; copy number 11: 5; copy number 14: 49; copy number 15: 12.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, sample TCGA-24-2023-01): tumor purity 0.92, ploidy 1.82, whole-genome doublings 0 (call status: legacy_call).

Homozygous deletions (total copy number 0; autosomes only): 44 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr8:7,355,517–7,896,716, 44 genes (within-gene range 0–3): ZNF705G, DEFB108C, DEFB4B, HSPD1P3, DEFB103B, SPAG11B, DEFB104B, DEFB106B, DEFB105B, DEFB107B, AC134684.11, PRR23D1, AC134684.12, FAM90A6P, FAM90A7P, FAM90A21P, FAM90A22P, FAM90A23P, OR7E157P, AC134684.1, AC134684.10, AC084121.2, AC084121.3, AC084121.1, OR7E154P, FAM90A14P, FAM90A18P, FAM90A16P, FAM90A8P, FAM90A17P, FAM90A19P, FAM90A9P, FAM90A10P, AC084121.4, PRR23D2, PRR23D3P, DEFB107A, DEFB105A, DEFB106A, DEFB104A, SPAG11A, DEFB103A, HSPD1P2, DEFB4A.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 671 genes in 26 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:164,343,005–164,357,364, 3 genes, copy number 9: NMNAT1P2, RNU5F-6P, HMGB3P6.
- chr1:201,688,259–201,829,559, 1 gene, copy number 14 (within-gene range 6–14): IPO9-AS1.
- chr1:201,808,611–202,028,692, 15 genes, copy number 14: MIR1231, IPO9, MIR6739, SHISA4, AL513217.1, LMOD1, TIMM17A, SNORA70H, RPL10P4, RNPEP, ELF3-AS1, MIR6740, ELF3, AL691482.3, AL691482.1.
- chr3:167,735,243–173,141,235, 101 genes, copy number 9–14 (broad region; genes not listed).
- chr3:175,675,087–178,385,479, 33 genes, copy number 9 (within-gene range 6–9): AC119744.1, UBE2V1P2, RNU6-1317P, NAALADL2-AS1, AC104640.1, ACTG1P23, EI24P1, AC104640.2, AC117434.1, LINC01208, MIR7977, RNA5SP147, LINC01209, MTND5P15, TBL1XR1, TBL1XR1-AS1, Y_RNA, RNU6-681P, LINC00501, ASS1P7, AC117465.1, LINC00578, RN7SKP52, AC026355.3, AC026355.1, AC026355.2, AC026355.4, LINC02015, AC007953.1, AC007953.2, RNU6-1120P, AC110992.1, AC117453.1.
- chr3:194,471,923–197,960,142, 131 genes, copy number 10 (within-gene range 6–10) (broad region; genes not listed).
- chr5:50,396,192–50,443,248, 1 gene, copy number 9: EMB.
- chr6:45,328,157–45,664,349, 1 gene, copy number 9 (within-gene range 6–9): RUNX2.
- chr6:45,573,346–47,042,350, 21 genes, copy number 9: RUNX2-AS1, CLIC5, RNU6-754P, AL035701.1, ENPP4, ENPP5, ACTG1P9, RCAN2, AL359633.1, AL035670.1, CYP39A1, SLC25A27, AL591242.1, TDRD6, PLA2G7, ANKRD66, AL161618.1, MEP1A, ADGRF5, ADGRF5-AS1, ADGRF1.
- chr6:93,416,951–94,194,658, 6 genes, copy number 9 (within-gene range 4–9): AL591519.1, AL356094.2, AL356094.1, AL391336.2, AL391336.1, AL157378.1.
- chr7:110,108,031–110,592,204, 3 genes, copy number 9 (within-gene range 6–9): AC073114.1, AC073114.2, AC073326.2.
- chr7:113,876,777–114,693,772, 7 genes, copy number 10: PPP1R3A, FOXP2, AC073626.2, AC073626.1, AC003992.1, RNA5SP238, MIR3666.
- chr7:151,148,589–151,439,124, 15 genes, copy number 10 (within-gene range 4–10): GBX1, ASB10, IQCA1L, H2BE1, ABCF2-H2BE1, ABCF2, CHPF2, MIR671, SMARCD3, AC021097.1, AC005486.1, NUB1, WDR86, WDR86-AS1, AC005996.1.
- chr8:73,290,242–73,370,601, 5 genes, copy number 9: RPL7, RDH10, RDH10-AS1, AC111149.1, AC111149.2.
- chr8:105,662,352–105,834,038, 4 genes, copy number 9: AC103853.1, AC103853.2, RPL12P24, AC090802.1.
- chr8:142,834,138–145,066,685, 142 genes, copy number 9 (broad region; genes not listed).
- chr10:806,914–1,737,525, 13 genes, copy number 9 (within-gene range 4–9): LARP4B, AL359878.2, AL359878.1, GTPBP4, IDI2, IDI2-AS1, IDI1, WDR37, LINC00200, ADARB2, AL392083.2, AL392083.1, AL513304.1.
- chr10:112,446,998–112,818,744, 1 gene, copy number 9 (within-gene range 6–9): VTI1A.
- chr10:112,634,170–113,917,194, 22 genes, copy number 9: MIR4295, AL139120.1, AL158212.5, AL158212.3, AL158212.4, AL158212.1, TCF7L2, AL158212.2, RPS15AP30, RNU7-165P, AL133482.1, PPIAP39, HABP2, NRAP, CASP7, AL592546.2, PLEKHS1, MIR4483, AL592546.1, DCLRE1A, NHLRC2, AL592546.3.
- chr10:131,966,455–132,942,823, 18 genes, copy number 9 (within-gene range 6–9): BNIP3, AL162274.2, AL162274.1, AL162274.3, JAKMIP3, AL512622.1, DPYSL4, STK32C, LRRC27, PWWP2B, AL451069.2, AL451069.3, LINC02870, AL451069.1, LINC01165, INPP5A, NKX6-2, CFAP46.
- chr11:22,625,509–25,141,023, 21 genes, copy number 9–15 (within-gene range 8–15): GAS2, RNA5SP338, SVIP, AC006299.1, CCDC179, LINC02718, AC100767.2, WIZP1, MIR8054, AC100767.1, THAP12P4, AC068472.1, LINC02726, AC100768.1, RNU6-783P, AC099842.1, LINC02686, Y_RNA, LUZP2, AC115990.1, AC087373.1.
- chr11:27,365,961–27,877,648, 12 genes, copy number 10 (within-gene range 6–10): LGR4, LGR4-AS1, AC100771.1, LIN7C, BDNF-AS, MIR8087, RNA5SP339, AC104563.1, LINC00678, BDNF, AC103796.1, CBX3P1.
- chr11:29,980,113–34,710,161, 86 genes, copy number 10 (broad region; genes not listed).
- chr16:15,395,754–15,625,028, 3 genes, copy number 9 (within-gene range 4–9): MPV17L, AC140504.1, BMERB1.
- chr17:31,094,927–31,382,116, 1 gene, copy number 9 (within-gene range 2–9): NF1.
- chr17:31,272,013–31,346,190, 5 genes, copy number 9: OMG, EVI2B, AC134669.1, EVI2A, AK4P1.

Autosomal genes at a single copy (total copy number 1): 3. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
